Somatic mutation profile of tumor specimen MBCProject_2531_T1_WES (aliquot MBCProject_2531_T1_WES_1) from CMI case MBCProject_2531, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_2531_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5519d32-f909-4c30-abf2-f62c71a9173f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2531_SALIVA (Saliva), aliquot MBCProject_2531_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b16517b-df9d-40b0-834f-1bc49b7b2f53

The open-access MAF lists 79 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Intron 8, 5'UTR 2, RNA 2, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATOH1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1258638483, COSV60037759; called by muse, mutect2
- CFTR | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as CD1213106; called by muse, mutect2, varscan2
- GPR84 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868793018, COSV57210290; called by muse, mutect2, varscan2
- GTF2F1 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556406656, COSV66724894; called by muse, mutect2, varscan2
- MAP7D3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs1040342425, COSV100286458; called by muse, mutect2, varscan2
- MGST3 | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs751324490; called by muse, mutect2, varscan2
- NIPAL3 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs894403223; called by muse, mutect2, varscan2
- NOX3 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99342711; called by muse, varscan2
- NTRK2 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1244676877; called by muse, mutect2, varscan2
- PCDHGA4 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.914); catalogued as COSV53927774; called by muse, mutect2, varscan2
- PLCE1 | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as rs200830976; called by muse, mutect2, varscan2
- PRIM2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1487134305; called by muse, mutect2, varscan2
- SHANK2 | c.3571G>A p.A1191T | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53584739; called by muse, mutect2, varscan2
- STK36 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55326695; called by muse, mutect2, varscan2
- SYNE1 | c.9209G>A p.R3070Q (on ENST00000367255 / NM_182961.4; = p.R3077Q on NM_033071.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs768750489, COSV55065334; called by muse, mutect2, varscan2
- TRIM51 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs755032979, COSV55267715; called by muse, mutect2, varscan2
- TUBA3C | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.636); catalogued as rs1012097257; called by muse, mutect2, varscan2
- AP2A2 | c.2018G>T p.G673V | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP5F1A | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CAPN2 | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CLU | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CMTR1 | c.1247T>G p.L416R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CROT | c.1496C>A p.A499D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX3X | c.926T>G p.I309S (on ENST00000399959; = p.I310S on NM_001356.5) | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAAF3 | c.1058C>A p.T353N (on ENST00000524407 / NM_001256715.2; = p.T400N on NM_178837.4) | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ELK1 | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRG3 | c.1211G>A p.C404Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- HTR5A | c.944T>G p.I315S | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- JPH4 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGALS3BP | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); called by muse, mutect2
- LILRB4 | c.466A>T p.I156F | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- LINGO2 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAN2A2 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NCKAP1L | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10C1 | c.529C>A p.Q177K (on ENST00000622521; = p.Q175K on NM_013941.3) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R12C | c.1073_1106del p.D358Gfs*55 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel
- PTPN13 | c.3680A>C p.H1227P (on ENST00000411767 / NM_080683.3; = p.H1208P on NM_006264.3) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- RGS11 | c.319-6C>A | Splice Region (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- RTL9 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SCAPER | c.2113C>G p.Q705E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- SKI | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC17A5 | c.1229T>G p.F410C | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SORCS2 | c.3147G>T p.K1049N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPACA1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYNGAP1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM132D | c.1498G>T p.V500F | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- TOMM20L | c.23T>A p.L8H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TUBD1 | c.1299A>C p.E433D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ZC3H6 | c.1646G>C p.G549A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, varscan2
- ZDHHC15 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ZNF629 | c.1072A>C p.S358R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CPNE2 | c.426C>A p.G142= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs572404586; called by muse, mutect2, varscan2
- FAM83A | c.177G>A p.E59= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs760070444; called by muse, mutect2, varscan2
- GET3 | c.795G>C p.L265= | Silent (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- JHY | c.657G>A p.E219= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs756526451; called by muse, mutect2, varscan2
- LILRB4 | c.465G>T p.L155= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- MAP2K7 | c.1251C>T p.F417= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs751683301; called by muse, varscan2
- MROH8 | c.1329A>T p.S443= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- OR4D10 | c.738G>T p.V246= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs778589438; called by muse, mutect2, varscan2
- PHIP | c.660C>G p.T220= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- PITPNM2 | c.1068G>A p.E356= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as rs1255702623; called by muse, mutect2, varscan2
- TRAJ32 | c.18T>C p.A6= | Silent (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- UNK | c.459C>T p.P153= | Silent (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- UTP14C | c.1524T>C p.T508= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.1551G>A p.R517= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- ZNF335 | c.3549G>A p.Q1183= | Silent (SNP) | VAF 35/165 reads (21%) | called by muse, mutect2, varscan2
- AAAS | c.936-48T>G | Intron (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- AL133268.3 | n.44C>A | RNA (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2, varscan2
- CDK11A | c.111+115T>C | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- CRAT | c.28-1115G>C | Intron (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- EXT2 | c.1173+14146C>G | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- HDAC4 | c.2265+44G>A | Intron (SNP) | VAF 53/142 reads (37%) | catalogued as rs753107883; called by muse, mutect2, varscan2
- IGFN1 | c.1242-898T>A | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- MZT2B | c.319+1126C>G | Intron (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- OR52B1P | n.488G>T | RNA (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40559238 C>T | 5'Flank (SNP) | VAF 7/30 reads (23%) | catalogued as rs1284735726; called by muse, mutect2, varscan2
- RPS27 | c.-19G>C | 5'UTR (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+8455G>C | Intron (SNP) | VAF 54/296 reads (18%) | called by muse, mutect2, varscan2
- SLC26A8 | c.-21G>A | 5'UTR (SNP) | VAF 13/132 reads (10%) | catalogued as rs1447370430; called by muse, mutect2, varscan2
